Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JS-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. LEFT KIDNEY, PARTIAL NEPHRECTOMY:
Renal cell carcinoma, papillary type II. See Key Pathologic Findings.
Pathologic stage: pT1a NX MX.
- B. DEEP MARGIN:
Renal parenchyma, no evidence of malignancy.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Key Pathological Findings

A: Kidney Resection
PROCEDURE:
Partial nephrectomy
SPECIMEN LATERALITY:
Left
TUMOR SIZE (largest tumor if multiple):
Dimension: 2.2 cm
MACROSCOPIC EXTENT OF TUMOR:
Tumor limited to kidney
HISTOLOGIC TYPE:
Papillary renal cell carcinoma
SARCOMATOID FEATURES:
Not identified
TUMOR NECROSIS:
< 2%
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):
II-III, predominantly III
MICROSCOPIC TUMOR EXTENSION:
Tumor limited to kidney
MARGINS:
Final surgical margin, free of malignancy
PERINEURAL INVASION:
Absent
ANGIOLYMPHATIC INVASION:
Absent
LYMPH-VASCULAR INVASION:
Absent
PRIMARY TUMOR (pT):
pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney
REGIONAL LYMPH NODES (pN):

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS
C64.9
JVO 4/28/14

[page 2 of 2]
pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM):
pMX

Specimen(s) Received

A LEFT PARTIAL NEPHRECTOMY FS
B DEEP MARGIN FS

Preoperative Diagnosis

Left renal tumor

Intraoperative Consultation

FSA1. LEFT PARTIAL NEPHRECTOMY:
Renal cell carcinoma, margin free of tumor.

FSB1. DEEP MARGIN:
Negative for malignancy.

This frozen section diagnosis was communicated to

I, _____, M.D., have performed the intraoperative consultation (s) and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "left partial nephrectomy" and consists of a 3.0 g, 2.5 x 2.0 x 2.0 cm partial nephrectomy specimen. The specimen has been oriented by the surgeon with ink. The margin of resection is re-inked in black. The capsule is irregular, tan to tan-red. When sectioning the specimen a tan-yellowish, partially hemorrhagic and necrotic mass is noted measuring 2.2 x 1.5 x 1.0 cm located at 0.1 cm from closest inked parenchymal margin of resection. The margin of resection is submitted for frozen section evaluation as FSA1 and the remaining tissue is entirely submitted in cassettes A2 and A3.
Representative tissue was submitted to Tissue Procurement.

B. The specimen is received fresh labeled "deep margin". The specimen consists of a fragment of dark red-brown soft tissue measuring 1.6 x 1.4 x 0.2 cm. The margin of resection had been marked by the surgeon with ink and re-inked in blue. The specimen is entirely submitted for frozen section evaluation as FSB1.

Source: NCI Genomic Data Commons file 3cc5b483-a8e8-401a-8122-cfc339c14775 (TCGA-2Z-A9JS.E6740AC4-64A2-4E53-887B-74C7EF3C9FAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).